Somatic mutation profile of tumor specimen TARGET-40-PAMHLF-01A (aliquot TARGET-40-PAMHLF-01A-01Y) from TARGET case TARGET-40-PAMHLF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.9 years (3,233 days).
Specimen TARGET-40-PAMHLF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37ab7a9-8b9a-46ce-ac8a-e28a5f512eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMHLF-10A (Blood Derived Normal), aliquot TARGET-40-PAMHLF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07870e86-a314-479e-8295-90c62232ff2c

The open-access MAF lists 38 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 9, Frame Shift Ins 4, Silent 4, 3'UTR 3, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 29/188 reads (15%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 33/41 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 27/170 reads (16%) | catalogued as rs745882580; called by mutect2, varscan2
- FKBP9 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99640209; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 42/162 reads (26%) | catalogued as rs777328830; called by mutect2, varscan2
- SCO1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs776887702, COSV55135166; called by muse, varscan2
- SLC8A3 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV63521722; called by muse, mutect2, varscan2
- ZFHX2 | c.5770dup p.V1924Gfs*3 | Frame Shift Ins (INS) | VAF 22/163 reads (13%) | catalogued as rs748108531; called by mutect2, varscan2
- CALM1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP1 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, varscan2
- CHD1L | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSRR | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- KLHL35 | c.1096A>T p.M366L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LINGO4 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- MUC16 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by mutect2, varscan2
- PCLO | c.6424G>T p.E2142* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- RIOK3 | c.1254+2T>C p.X418_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- RSBN1L | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZDBF2 | c.2069T>C p.V690A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHAF1B | c.1377C>G p.P459= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- GAS6 | c.867C>G p.A289= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- INPP5D | c.1194G>A p.Q398= (on ENST00000445964 / NM_001017915.3; = p.Q397= on NM_005541.5) | Silent (SNP) | VAF 36/167 reads (22%) | catalogued as rs1168506572; called by muse, mutect2, varscan2
- TMEM266 | c.726C>T p.D242= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs747155045, COSV66381207; called by muse, varscan2
- ARAP3 | c.972+102dup | Intron (INS) | VAF 7/38 reads (18%) | catalogued as rs1467963658; called by pindel, varscan2
- ARHGAP45 | c.651-35G>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- CMTM5 | c.*10T>A | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- CRIP3 | c.*18dup | 3'UTR (INS) | VAF 10/52 reads (19%) | catalogued as rs745781004; called by mutect2, varscan2
- DNAJC6 | c.495+30G>T | Intron (SNP) | VAF 4/106 reads (4%) | called by muse, mutect2
- GRM6 | c.*85C>T | 3'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- IWS1 | chr2:127526782 C>T | 5'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- IWS1 | chr2:127526783 C>T | 5'Flank (SNP) | VAF 5/15 reads (33%) | catalogued as rs377279967; called by muse, varscan2
- NCR2 | c.644+806T>C | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- PCK2 | c.1234+182G>A | Intron (SNP) | VAF 7/12 reads (58%) | catalogued as rs991927367; called by muse, mutect2, varscan2
- PRPF3 | c.277-30C>T | Intron (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- RFX1 | c.1496+99del | Intron (DEL) | VAF 3/8 reads (38%) | called by mutect2, varscan2
- SEC24C | c.2863-53dup | Intron (INS) | VAF 17/128 reads (13%) | catalogued as rs940989201; called by mutect2, varscan2
- SHFL | c.235-30dup | Intron (INS) | VAF 12/108 reads (11%) | catalogued as rs761104658; called by mutect2, varscan2
- VWFP1 | n.1479dup | RNA (INS) | VAF 10/73 reads (14%) | catalogued as rs1264435414; called by mutect2, varscan2
